Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A140, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A140-01A (Primary Tumor).

140-0-3

Infiltrating Duct Carcinoma, no.

8500/3

LW

Site: breast, NOS
C50.9

11/22/10

page 1 / 1

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Examination No.:

Patient: PESEL: Age: Gender: F

Material: Multiple organ resection – left breast with axillary tissues

Unit in charge:

Physician in charge:

Material collected on:

Material received on

Expected time of examination: up to

Clinical diagnosis: Cancer of the left breast.

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in 75% of neoplastic cell nuclei. Progesterone receptors found in 10% of neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO.
Positive reaction in invasive cancerous cells (Score = 3+)

Compliance validated by:

Examination performed on

Macroscopic description:

Left breast, sized 22 x 17 x 5 cm, removed along with axillary tissues sized 9 x 6 x 2 cm and a skin flap of 23 x 11 cm. Tumour sized 3.1 x 1.5 x 1.7 cm in the upper outer quadrant, placed 6 cm from the upper edge, 0.7 cm from the base and 1.2 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum - NHG3 (2+3+3/21 mitoses/10 HPF - visual area: 0.55mm).

Glandular tissue outside the tumour showing lesions of the type mastopathia fibrosa et cystica, hyperplasia

ductalis simplex (UDH).

Axillary lymph nodes:

Metastases carcinomatosae in lymphonodo (No I/XV).

Infiltratio capsulae lymphonodi.

Histopathological diagnosis:

Carcinoma ductale invasivum mammae sinistrae.

Metastases carcinomatosae in lymphonodo axillae (No I/XV). (NHG3; pT2; pN1a).

DUCTAL INVASIVE CARCINOMA

NEOPLASTIC AXILLARY LYMPH NODE (I/XV)

Compliance validated.

Source: NCI Genomic Data Commons file 1f51fe3e-7f5c-4850-9ec2-24f3bc95fc8b (TCGA-D8-A140.D78476E6-799F-4DED-A219-CBFE2DE3C77B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).